Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A7XO, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A7XO-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor is located in a sublobes VI, VII, ill-margins with 7x7x7cm in size, soft, solid, gray-white in cutting section.

Microscopic Description: Tumor cells form the trabecular patterns connecting each other, or sheets patterns. The tumor cells retain apolygonal shape and have round vesicular nuclei with prominent nucleoli. The amount of cytoplasm are moderate and the cytoplasm is basophilic or vacuolated. Nuclei are irregularly large and hyperchromatic with prominent nucleoli. Mitoses are present. Tumor invades into vessels or normal hepatic tissue. Stroma is fibrous.

Diagnosis Details: Hepatocellular carcinoma, moderately-differentiated

Comments:

Formatted Path Reports: LIVER TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor size: 7 x 7 x 5 cm

Focality: Not specified

Histologic type: Hepatocellular carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Multiple tumors more than 5.0 cm

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Tumor in sublobes 6 and 7.

Comments: None

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

Q1 10/10/13

Source: NCI Genomic Data Commons file b31b15fa-efef-4370-99f2-971618fe8213 (TCGA-ED-A7XO.3FC3BB34-8E4A-4422-BFEF-58B15947F032.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).